Somatic mutation profile of tumor specimen C3N-00829-01 (aliquot CPT0013210010) from CPTAC case C3N-00829, project CPTAC-3 (Other and unspecified parts of tongue — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 53.1 years (19,384 days).
Specimen C3N-00829-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Tongue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f036affa-753e-44f7-9887-98a3f16cdd23.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00829-31 (Blood Derived Normal), aliquot CPT0013310002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/71565660-92d9-4035-95b2-88fd07ae33ae

The open-access MAF lists 213 somatic variants for this specimen: 145 protein-altering or splice-affecting, 41 silent, 27 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 128, Silent 41, Intron 9, Nonsense Mutation 9, 3'UTR 6, RNA 5, 5'Flank 4, Frame Shift Del 3, Splice Region 3, 5'UTR 2, Nonstop Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.646G>A p.V216M | Missense Mutation (SNP) | VAF 219/470 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730882025, CM159291, CX952222, COSV52671096, COSV52751864, COSV53384298; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA3 | c.3805G>C p.E1269Q | Missense Mutation (SNP) | VAF 41/233 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.325); catalogued as COSV57061176; called by muse, mutect2, varscan2
- ACAN | c.2137C>T p.P713S | Missense Mutation (SNP) | VAF 38/302 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV61366645; called by muse, mutect2, varscan2
- ADAM22 | c.1393G>C p.E465Q | Missense Mutation (SNP) | VAF 46/171 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV55976929; called by muse, mutect2, varscan2
- ADCY3 | c.2524A>G p.M842V | Missense Mutation (SNP) | VAF 64/252 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.037); catalogued as rs779417481; called by muse, mutect2, varscan2
- ANAPC1 | c.2110G>C p.D704H | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV100594493; called by muse, mutect2, varscan2
- ASPM | c.4592G>A p.R1531H | Missense Mutation (SNP) | VAF 144/408 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs200681905, COSV54139741, COSV99660913; called by muse, mutect2, varscan2
- AXDND1 | c.2598G>C p.E866D | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.551); catalogued as rs369850989; called by muse, mutect2, varscan2
- BEND3 | c.1685G>C p.S562T | Missense Mutation (SNP) | VAF 41/234 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.058); catalogued as rs1554231496; called by muse, mutect2, varscan2
- BIRC6 | c.55A>G p.S19G | Missense Mutation (SNP) | VAF 88/248 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.029); catalogued as rs1051001712; called by muse, mutect2, varscan2
- CD58 | c.222C>G p.F74L | Missense Mutation (SNP) | VAF 84/233 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as COSV65664737; called by muse, mutect2, varscan2
- CDRT1 | c.401C>T p.A134V | Missense Mutation (SNP) | VAF 54/482 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as rs746945941; called by muse, mutect2, varscan2
- CFAP54 | c.6767C>T p.T2256I | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.014); catalogued as rs141857286, COSV61573988; called by muse, mutect2, varscan2
- CFD | c.85G>A p.G29S | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs754468619; called by muse, mutect2, varscan2
- CMYA5 | c.1342C>T p.Q448* | Nonsense Mutation (SNP) | VAF 87/226 reads (38%) | catalogued as rs1239163467; called by muse, mutect2, varscan2
- CRCP | c.11A>G p.K4R | Missense Mutation (SNP) | VAF 25/191 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV100647774; called by muse, mutect2, varscan2
- DDX50 | c.1139A>T p.D380V | Missense Mutation (SNP) | VAF 50/276 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs575007030; called by muse, mutect2, varscan2
- DLGAP1 | c.1115G>A p.R372Q | Missense Mutation (SNP) | VAF 136/530 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as rs1188288808, COSV59839385; called by muse, mutect2, varscan2
- FXYD6 | c.149C>T p.S50L | Missense Mutation (SNP) | VAF 53/346 reads (15%) | SIFT tolerated (0.77); PolyPhen benign (0.043); catalogued as rs571985984, COSV52805106; called by muse, mutect2, varscan2
- GLRA3 | c.685C>G p.R229G | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT tolerated (0.64); PolyPhen benign (0.007); catalogued as COSV99928303; called by muse, mutect2, varscan2
- HS3ST3A1 | c.679G>A p.A227T | Missense Mutation (SNP) | VAF 55/310 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.06); catalogued as rs750522076, COSV52372487; called by muse, mutect2, varscan2
- ISL1 | c.335G>A p.R112H | Missense Mutation (SNP) | VAF 74/450 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV57932848; called by muse, mutect2, varscan2
- KCNH4 | c.2558G>A p.R853K | Missense Mutation (SNP) | VAF 33/121 reads (27%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV99236910; called by muse, mutect2, varscan2
- KIF2B | c.415C>A p.P139T | Missense Mutation (SNP) | VAF 25/232 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.321); catalogued as rs1182060050; called by muse, mutect2, varscan2
- LARGE2 | c.1798C>T p.R600C | Missense Mutation (SNP) | VAF 59/288 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs575481241; called by muse, mutect2, varscan2
- LARP1 | c.1907A>G p.D636G (on ENST00000518297 / NM_033551.3; = p.D559G on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/121 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.341); catalogued as COSV60426194; called by muse, mutect2, varscan2
- LCN6 | c.302C>A p.S101* | Nonsense Mutation (SNP) | VAF 40/230 reads (17%) | catalogued as COSV100366439; called by muse, mutect2, varscan2
- MADD | c.310C>T p.R104* | Nonsense Mutation (SNP) | VAF 41/237 reads (17%) | catalogued as rs766120355, COSV60625037; called by muse, mutect2, varscan2
- MYO6 | c.1612C>A p.P538T | Missense Mutation (SNP) | VAF 71/479 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as COSV64121156; called by muse, mutect2, varscan2
- OR10A4 | c.632C>T p.P211L | Missense Mutation (SNP) | VAF 46/290 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV104429327; called by muse, mutect2, varscan2
- PDCD6IP | c.2428C>G p.P810A | Missense Mutation (SNP) | VAF 24/186 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.098); catalogued as COSV56245598; called by muse, mutect2, varscan2
- POLR1F | c.544T>C p.F182L | Missense Mutation (SNP) | VAF 89/411 reads (22%) | SIFT tolerated (0.61); PolyPhen benign (0.039); catalogued as rs1479367551; called by muse, mutect2, varscan2
- POMT1 | c.1859G>A p.R620Q | Missense Mutation (SNP) | VAF 330/649 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as rs202140413, CM1510281; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRAC1 | c.113G>A p.R38K | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.015); catalogued as rs991816688; called by muse, mutect2, varscan2
- PSMB9 | c.422G>A p.R141Q | Missense Mutation (SNP) | VAF 62/284 reads (22%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.85); catalogued as rs747761347; called by muse, mutect2, varscan2
- RNASET2 | c.532G>A p.V178M | Missense Mutation (SNP) | VAF 56/352 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs1239284254; called by muse, mutect2, varscan2
- SDC3 | c.694C>A p.P232T | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0.01); catalogued as rs147765782; called by muse, mutect2
- SDK2 | c.5593+4C>T | Splice Region (SNP) | VAF 56/259 reads (22%) | catalogued as rs376714866; called by muse, mutect2, varscan2
- SELP | c.2345C>T p.T782M | Missense Mutation (SNP) | VAF 38/275 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.682); catalogued as rs758040258, COSV55248258, COSV55256313; called by muse, mutect2, varscan2
- SIDT1 | c.2030G>A p.R677Q | Missense Mutation (SNP) | VAF 48/390 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.147); catalogued as COSV104393652; called by muse, mutect2, varscan2
- SPATA31A3 | c.2058G>A p.M686I | Missense Mutation (SNP) | VAF 42/388 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs1038794706; called by muse, mutect2, varscan2
- STK11IP | c.197C>T p.P66L | Missense Mutation (SNP) | VAF 150/375 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55258513; called by muse, mutect2, varscan2
- TMEM190 | c.176G>A p.R59Q | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as rs1048232172, COSV52582168; called by muse, mutect2, varscan2
- TMTC2 | c.1226C>G p.T409R | Missense Mutation (SNP) | VAF 42/268 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as rs754452313, COSV58263248; called by muse, mutect2, varscan2
- TMX4 | c.796G>T p.E266* | Nonsense Mutation (SNP) | VAF 33/342 reads (10%) | catalogued as COSV99851644; called by muse, mutect2
- TOP3B | c.139G>A p.G47S | Missense Mutation (SNP) | VAF 26/196 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.718); catalogued as rs1179018819; called by muse, mutect2, varscan2
- VENTX | c.278G>A p.R93H | Missense Mutation (SNP) | VAF 27/164 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs751897446; called by muse, mutect2, varscan2
- WIZ | c.4033C>T p.P1345S (on ENST00000673675 / NM_001371589.1; = p.P250S on NM_021241.3) | Missense Mutation (SNP) | VAF 46/175 reads (26%) | SIFT tolerated (0.5); PolyPhen benign (0.108); catalogued as rs373041125; called by muse, mutect2, varscan2
- ZNF350 | c.1229C>T p.A410V | Missense Mutation (SNP) | VAF 40/208 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.37); catalogued as rs771994012, COSV54709296; called by muse, mutect2, varscan2
- ZNF460 | c.1393C>T p.R465* | Nonsense Mutation (SNP) | VAF 32/221 reads (14%) | catalogued as rs1179718453; called by muse, mutect2, varscan2
- ZNF658 | c.2126C>T p.T709M | Missense Mutation (SNP) | VAF 151/498 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs577867027; called by muse, mutect2, varscan2
- ABHD13 | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 132/348 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- AC090517.4 | c.1631C>G p.P544R | Missense Mutation (SNP) | VAF 36/279 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- ACTR5 | c.1738C>T p.P580S | Missense Mutation (SNP) | VAF 31/243 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ADAM7 | c.1744C>A p.Q582K | Missense Mutation (SNP) | VAF 56/156 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- AFF2 | c.1067G>C p.C356S | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ANKRD31 | c.2894C>T p.T965I | Missense Mutation (SNP) | VAF 32/240 reads (13%) | SIFT tolerated (0.85); PolyPhen benign (0); called by muse, mutect2, varscan2
- APOM | c.19G>C p.A7P | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- ASXL2 | c.4058A>T p.N1353I | Missense Mutation (SNP) | VAF 84/279 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ASZ1 | c.1026G>C p.E342D | Missense Mutation (SNP) | VAF 32/223 reads (14%) | SIFT tolerated (0.78); PolyPhen benign (0); called by muse, mutect2, varscan2
- BIRC3 | c.224del p.N75Tfs*25 | Frame Shift Del (DEL) | VAF 52/305 reads (17%) | called by mutect2, pindel, varscan2
- C3 | c.1858G>A p.V620M | Missense Mutation (SNP) | VAF 50/261 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- C9orf135 | c.184T>A p.Y62N | Missense Mutation (SNP) | VAF 34/152 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCDC158 | c.2903G>A p.G968E | Missense Mutation (SNP) | VAF 23/161 reads (14%) | SIFT tolerated (0.86); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- CCDC74B | c.312C>G p.N104K | Missense Mutation (SNP) | VAF 25/185 reads (14%) | SIFT tolerated (0.91); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- CCNB3 | c.1126G>A p.E376K | Missense Mutation (SNP) | VAF 62/181 reads (34%) | SIFT tolerated (0.69); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CDC42BPB | c.3643A>T p.I1215F | Missense Mutation (SNP) | VAF 79/492 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- CEP68 | c.2174A>G p.Y725C | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CLCN2 | c.2697A>C p.*899Cext*84 | Nonstop Mutation (SNP) | VAF 237/553 reads (43%) | called by muse, mutect2, varscan2
- COL28A1 | c.1048C>A p.P350T | Missense Mutation (SNP) | VAF 19/181 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.188); called by muse, mutect2
- COPB2 | c.706A>T p.S236C | Missense Mutation (SNP) | VAF 87/307 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CRAMP1 | c.12G>C p.K4N | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.708); called by muse, mutect2
- CUBN | c.7681T>A p.S2561T | Missense Mutation (SNP) | VAF 50/261 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- DARS2 | c.1656C>G p.I552M | Missense Mutation (SNP) | VAF 60/435 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.581); called by muse, mutect2, varscan2
- DEPTOR | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 19/529 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2
- DLX5 | c.444G>C p.Q148H | Missense Mutation (SNP) | VAF 91/568 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNM1 | c.1531A>T p.T511S | Missense Mutation (SNP) | VAF 28/174 reads (16%) | SIFT tolerated (0.56); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- DPYS | c.1361G>T p.S454I | Missense Mutation (SNP) | VAF 259/902 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- DSCAM | c.3358A>G p.I1120V | Missense Mutation (SNP) | VAF 7/198 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- EHBP1L1 | c.3221C>T p.A1074V | Missense Mutation (SNP) | VAF 25/122 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ENAM | c.1358A>C p.N453T | Missense Mutation (SNP) | VAF 29/182 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- EPB41L2 | c.626A>C p.Q209P | Missense Mutation (SNP) | VAF 70/383 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EPS15 | c.2272G>C p.E758Q | Missense Mutation (SNP) | VAF 60/163 reads (37%) | SIFT tolerated (0.32); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- FOXC1 | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 68/545 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GAA | c.2316G>A p.W772* | Nonsense Mutation (SNP) | VAF 18/351 reads (5%) | called by muse, mutect2
- GABBR2 | c.612C>G p.D204E | Missense Mutation (SNP) | VAF 25/161 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- GABRA6 | c.91A>G p.N31D | Missense Mutation (SNP) | VAF 117/371 reads (32%) | SIFT tolerated (0.6); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GCGR | c.498C>G p.L166= | Splice Region (SNP) | VAF 25/179 reads (14%) | called by muse, mutect2, varscan2
- GRK6 | c.769G>A p.D257N | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- HGD | c.514A>G p.M172V | Missense Mutation (SNP) | VAF 133/546 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ICE1 | c.1958G>C p.C653S | Missense Mutation (SNP) | VAF 18/226 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0.006); called by muse, mutect2
- ILF3 | c.1403C>T p.P468L | Missense Mutation (SNP) | VAF 28/191 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.644); called by muse, mutect2, varscan2
- ITSN1 | c.2322G>A p.V774= | Splice Region (SNP) | VAF 39/173 reads (23%) | called by muse, mutect2, varscan2
- JMJD1C | c.3173G>A p.S1058N | Missense Mutation (SNP) | VAF 38/209 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.397); called by muse, mutect2, varscan2
- KCNJ16 | c.851_855del p.Y284Wfs*2 | Frame Shift Del (DEL) | VAF 87/333 reads (26%) | called by mutect2, pindel, varscan2
- KIAA0753 | c.2888T>G p.L963* | Nonsense Mutation (SNP) | VAF 18/135 reads (13%) | called by muse, mutect2, varscan2
- KIAA0753 | c.998G>A p.C333Y | Missense Mutation (SNP) | VAF 26/335 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.013); called by muse, mutect2
- LIMD2 | c.304T>C p.Y102H | Missense Mutation (SNP) | VAF 78/329 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LTK | c.1231G>C p.D411H | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- MDGA2 | c.847T>A p.Y283N | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- MLXIP | c.284A>G p.K95R | Missense Mutation (SNP) | VAF 53/286 reads (19%) | SIFT tolerated (0.38); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- MUCL1 | c.37_58+21del p.X13_splice | Splice Site (DEL) | VAF 22/222 reads (10%) | called by mutect2, pindel
- MXRA5 | c.7087G>T p.V2363L | Missense Mutation (SNP) | VAF 62/153 reads (41%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.763); called by muse, mutect2, varscan2
- MYH4 | c.2657A>C p.Q886P | Missense Mutation (SNP) | VAF 36/155 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.531); called by muse, varscan2
- MYO1E | c.1826A>G p.Y609C | Missense Mutation (SNP) | VAF 113/398 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- NAV3 | c.2696C>G p.T899S | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- NDNF | c.1583C>T p.T528I | Missense Mutation (SNP) | VAF 49/339 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- NEB | c.8198C>A p.T2733N | Missense Mutation (SNP) | VAF 16/168 reads (10%) | SIFT tolerated (0.45); PolyPhen benign (0.003); called by muse, mutect2
- NLRP7 | c.2417C>G p.A806G (on ENST00000340844 / NM_206828.3; = p.A778G on NM_139176.3) | Missense Mutation (SNP) | VAF 47/299 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- OR10G4 | c.55C>A p.P19T | Missense Mutation (SNP) | VAF 39/240 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PAPPA2 | c.3565G>A p.D1189N | Missense Mutation (SNP) | VAF 60/235 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PCDH15 | c.3863C>A p.S1288Y | Missense Mutation (SNP) | VAF 44/206 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- PHRF1 | c.4403C>G p.T1468R (on ENST00000264555 / NM_001286581.2; = p.T1467R on NM_020901.4) | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.327); called by muse, mutect2
- PHTF2 | c.167A>T p.Q56L (on ENST00000248550 / NM_001366089.1; = p.Q22L on NM_020432.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- PLG | c.1478G>T p.R493M | Missense Mutation (SNP) | VAF 58/368 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PPP2R1A | c.714G>T p.E238D | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRAG1 | c.3751A>T p.K1251* | Nonsense Mutation (SNP) | VAF 104/263 reads (40%) | called by muse, mutect2, varscan2
- PTGER2 | c.511C>T p.P171S | Missense Mutation (SNP) | VAF 24/181 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- PTPRQ | c.5578T>G p.F1860V (on ENST00000616559; = p.F1818V on NM_001145026.2) | Missense Mutation (SNP) | VAF 34/204 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.041); called by muse, varscan2
- RAB11FIP4 | c.960C>G p.S320R | Missense Mutation (SNP) | VAF 39/265 reads (15%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- RET | c.245A>G p.E82G | Missense Mutation (SNP) | VAF 62/435 reads (14%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- RNF150 | c.1151A>T p.D384V | Missense Mutation (SNP) | VAF 27/250 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- SAMD9L | c.2131A>G p.K711E | Missense Mutation (SNP) | VAF 34/202 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, varscan2
- SEC24B | c.2894C>G p.S965* | Nonsense Mutation (SNP) | VAF 69/244 reads (28%) | called by muse, mutect2, varscan2
- SETX | c.5651T>C p.V1884A | Missense Mutation (SNP) | VAF 65/477 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- SH3RF1 | c.2414C>G p.A805G | Missense Mutation (SNP) | VAF 33/169 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- SI | c.5013T>A p.F1671L | Missense Mutation (SNP) | VAF 52/519 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.003); called by muse, mutect2
- SIRT4 | c.766C>G p.L256V | Missense Mutation (SNP) | VAF 29/148 reads (20%) | SIFT tolerated (0.52); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- SLC8A2 | c.1678C>T p.R560C | Missense Mutation (SNP) | VAF 27/157 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- SLITRK3 | c.266T>C p.M89T | Missense Mutation (SNP) | VAF 21/220 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.112); called by muse, mutect2
- SNTB1 | c.649C>T p.P217S | Missense Mutation (SNP) | VAF 27/484 reads (6%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.714); called by muse, mutect2
- SPTB | c.4621G>A p.G1541R | Missense Mutation (SNP) | VAF 24/157 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); called by muse, mutect2
- STAP2 | c.97G>T p.D33Y | Missense Mutation (SNP) | VAF 32/134 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- TASOR2 | c.6871G>C p.E2291Q | Missense Mutation (SNP) | VAF 39/270 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TENM3 | c.2857A>T p.S953C | Missense Mutation (SNP) | VAF 65/303 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.431); called by muse, mutect2, varscan2
- TGFB3 | c.445G>A p.A149T | Missense Mutation (SNP) | VAF 39/324 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- THUMPD2 | c.712T>A p.F238I | Missense Mutation (SNP) | VAF 39/244 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.715); called by muse, mutect2, varscan2
- TMEM259 | c.856G>C p.V286L | Missense Mutation (SNP) | VAF 26/210 reads (12%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- TNFRSF18 | c.158A>C p.H53P | Missense Mutation (SNP) | VAF 51/243 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TNIP3 | c.137G>C p.R46T (on ENST00000509841 / NM_001244764.2; = p.R39T on NM_001128843.2) | Missense Mutation (SNP) | VAF 29/216 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- TP53BP1 | c.2377G>C p.E793Q | Missense Mutation (SNP) | VAF 55/326 reads (17%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- TTBK2 | c.2304A>T p.R768S | Missense Mutation (SNP) | VAF 50/381 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- USP7 | c.994A>G p.I332V | Missense Mutation (SNP) | VAF 32/205 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.404); called by muse, mutect2, varscan2
- ZC3H6 | c.1100A>G p.D367G | Missense Mutation (SNP) | VAF 54/159 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.321); called by muse, mutect2
- ZNF132 | c.1689_1690del p.R563Sfs*9 | Frame Shift Del (DEL) | VAF 72/237 reads (30%) | called by pindel, varscan2
- ABL2 | c.1773C>T p.N591= (on ENST00000502732 / NM_007314.4; = p.N576= on NM_005158.5) | Silent (SNP) | VAF 57/336 reads (17%) | catalogued as rs949926413; called by muse, mutect2, varscan2
- ACADL | c.696T>G p.L232= | Silent (SNP) | VAF 54/265 reads (20%) | called by muse, mutect2, varscan2
- ADAMTS15 | c.129G>C p.R43= | Silent (SNP) | VAF 10/53 reads (19%) | called by muse, mutect2, varscan2
- ASL | c.939C>T p.T313= | Silent (SNP) | VAF 65/484 reads (13%) | called by muse, mutect2, varscan2
- C3orf20 | c.2004G>C p.L668= | Silent (SNP) | VAF 35/219 reads (16%) | called by muse, mutect2, varscan2
- CCDC88B | c.3522G>A p.E1174= | Silent (SNP) | VAF 18/108 reads (17%) | catalogued as rs1277054387; called by muse, mutect2, varscan2
- CEP131 | c.3162C>G p.L1054= (on ENST00000269392 / NM_001319228.2; = p.L1051= on NM_014984.4) | Silent (SNP) | VAF 25/152 reads (16%) | called by muse, mutect2, varscan2
- CFAP65 | c.3948C>T p.P1316= | Silent (SNP) | VAF 49/234 reads (21%) | catalogued as rs1184801735; called by muse, mutect2, varscan2
- CYP4V2 | c.894C>A p.A298= | Silent (SNP) | VAF 94/250 reads (38%) | called by muse, mutect2, varscan2
- DENND4C | c.4035C>T p.S1345= (on ENST00000434457 / NM_001330640.2; = p.S1296= on NM_017925.7) | Silent (SNP) | VAF 66/503 reads (13%) | called by muse, mutect2, varscan2
- DGKB | c.1284G>C p.L428= | Silent (SNP) | VAF 64/319 reads (20%) | called by muse, mutect2, varscan2
- ERBB4 | c.3381G>A p.R1127= | Silent (SNP) | VAF 126/312 reads (40%) | catalogued as COSV61520564; called by muse, mutect2, varscan2
- FCSK | c.2043G>C p.L681= | Silent (SNP) | VAF 15/188 reads (8%) | called by muse, mutect2
- GMIP | c.873A>G p.R291= | Silent (SNP) | VAF 22/146 reads (15%) | catalogued as rs747421097; called by muse, mutect2, varscan2
- GOLGA8R | c.783G>A p.Q261= | Silent (SNP) | VAF 26/352 reads (7%) | catalogued as rs1189417896; called by muse, mutect2
- GTPBP3 | c.90C>T p.P30= | Silent (SNP) | VAF 22/292 reads (8%) | catalogued as rs1470781128; called by muse, mutect2
- HEATR1 | c.3312C>T p.I1104= | Silent (SNP) | VAF 16/120 reads (13%) | called by muse, mutect2
- HIC2 | c.1569C>T p.H523= | Silent (SNP) | VAF 52/277 reads (19%) | catalogued as rs780721041; called by muse, mutect2, varscan2
- KCP | c.252G>C p.L84= | Silent (SNP) | VAF 21/49 reads (43%) | called by muse, mutect2, varscan2
- KIAA1109 | c.5928A>G p.E1976= | Silent (SNP) | VAF 23/119 reads (19%) | called by muse, mutect2, varscan2
- MICALL1 | c.1248G>A p.T416= | Silent (SNP) | VAF 64/251 reads (25%) | catalogued as rs764708989; called by muse, mutect2, varscan2
- MROH2B | c.18G>A p.E6= | Silent (SNP) | VAF 28/221 reads (13%) | called by muse, mutect2, varscan2
- NEUROD1 | c.681C>G p.P227= | Silent (SNP) | VAF 48/245 reads (20%) | catalogued as COSV54549711; called by muse, mutect2, varscan2
- NLGN1 | c.2268C>T p.T756= | Silent (SNP) | VAF 42/375 reads (11%) | catalogued as rs571981164, COSV100849223; called by muse, mutect2, varscan2
- NOP14 | c.726A>G p.R242= | Silent (SNP) | VAF 33/154 reads (21%) | called by muse, mutect2, varscan2
- OSBP2 | c.2631G>C p.T877= | Silent (SNP) | VAF 31/197 reads (16%) | called by muse, mutect2, varscan2
- PCDHA12 | c.1281G>A p.A427= | Silent (SNP) | VAF 180/436 reads (41%) | catalogued as COSV56476489; called by muse, mutect2, varscan2
- PCDHB14 | c.1488G>T p.R496= | Silent (SNP) | VAF 185/491 reads (38%) | called by muse, mutect2, varscan2
- PCDHGA7 | c.1338C>T p.N446= | Silent (SNP) | VAF 13/186 reads (7%) | catalogued as COSV53916861; called by muse, mutect2
- PCDHGC3 | c.2253G>A p.L751= | Silent (SNP) | VAF 62/286 reads (22%) | called by muse, mutect2, varscan2
- PELI2 | c.66G>T p.L22= | Silent (SNP) | VAF 8/128 reads (6%) | called by muse, mutect2
- PLCE1 | c.4911A>G p.K1637= | Silent (SNP) | VAF 27/214 reads (13%) | called by muse, mutect2, varscan2
- RALGAPA2 | c.934T>C p.L312= | Silent (SNP) | VAF 12/119 reads (10%) | called by muse, mutect2
- SLC9A5 | c.1227G>C p.G409= | Silent (SNP) | VAF 10/188 reads (5%) | called by muse, mutect2
- SOX11 | c.585C>T p.G195= | Silent (SNP) | VAF 13/99 reads (13%) | called by muse, mutect2
- TAF7 | c.867A>G p.K289= | Silent (SNP) | VAF 78/205 reads (38%) | called by muse, mutect2, varscan2
- TEX14 | c.3762G>A p.L1254= (on ENST00000240361 / NM_001201457.2; = p.L1208= on NM_031272.5) | Silent (SNP) | VAF 52/208 reads (25%) | called by muse, mutect2, varscan2
- TMC5 | c.1557G>A p.G519= (on ENST00000396229 / NM_001105248.1; = p.G273= on NM_024780.5) | Silent (SNP) | VAF 38/264 reads (14%) | called by muse, varscan2
- XKR6 | c.120C>T p.G40= | Silent (SNP) | VAF 37/195 reads (19%) | catalogued as rs1053342995; called by muse, mutect2, varscan2
- YRDC | c.312C>T p.R104= | Silent (SNP) | VAF 15/60 reads (25%) | called by muse, mutect2, varscan2
- ZNF717 | c.1980A>T p.S660= | Silent (SNP) | VAF 75/587 reads (13%) | called by muse, mutect2, varscan2
- AC016747.4 | n.486C>G | RNA (SNP) | VAF 56/161 reads (35%) | called by muse, mutect2, varscan2
- AL136439.1 | chr13:27665810 C>T | 3'Flank (SNP) | VAF 47/297 reads (16%) | called by muse, mutect2, varscan2
- ARHGEF4 | chr2:130914992 A>T | 5'Flank (SNP) | VAF 46/130 reads (35%) | called by muse, mutect2, varscan2
- C8orf31 | n.539-444C>T | Intron (SNP) | VAF 29/382 reads (8%) | called by muse, mutect2
- CFAP91 | c.1680+9T>A | Intron (SNP) | VAF 49/418 reads (12%) | called by muse, mutect2, varscan2
- EARS2 | c.140-782G>A | Intron (SNP) | VAF 6/52 reads (12%) | catalogued as rs1376278392; called by muse, mutect2
- FAM90A20P | n.295G>A | RNA (SNP) | VAF 41/321 reads (13%) | called by muse, mutect2, varscan2
- FGFR2 | c.939+1174G>A | Intron (SNP) | VAF 61/416 reads (15%) | called by muse, mutect2, varscan2
- GRM6 | c.2125-40C>G | Intron (SNP) | VAF 21/99 reads (21%) | called by muse, mutect2, varscan2
- GRM6 | c.2125-41C>A | Intron (SNP) | VAF 21/99 reads (21%) | called by muse, mutect2, varscan2
- HDGF | c.*75C>G | 3'UTR (SNP) | VAF 7/21 reads (33%) | called by muse, mutect2, varscan2
- HTR3A | c.*123G>A | 3'UTR (SNP) | VAF 100/559 reads (18%) | catalogued as rs747454326; called by muse, mutect2, varscan2
- IDH3A | c.-31G>T | 5'UTR (SNP) | VAF 20/111 reads (18%) | called by muse, mutect2, varscan2
- KIF18B | c.*10T>G | 3'UTR (SNP) | VAF 65/351 reads (19%) | called by muse, mutect2, varscan2
- KIFC3 | chr16:57803010 C>A | 5'Flank (SNP) | VAF 51/284 reads (18%) | called by muse, mutect2, varscan2
- LINC01387 | n.132C>T | RNA (SNP) | VAF 18/198 reads (9%) | called by muse, mutect2
- LINC01949 | n.1117G>A | RNA (SNP) | VAF 6/45 reads (13%) | called by muse, mutect2, varscan2
- MIR548I4 | n.4T>C | RNA (SNP) | VAF 9/26 reads (35%) | called by muse, mutect2, varscan2
- PSME2 | c.-22G>C | 5'UTR (SNP) | VAF 165/300 reads (55%) | called by muse, mutect2, varscan2
- SCAP | c.252+20C>T | Intron (SNP) | VAF 31/136 reads (23%) | called by muse, mutect2, varscan2
- TNFRSF13C | c.*43C>A | 3'UTR (SNP) | VAF 11/74 reads (15%) | called by muse, mutect2, varscan2
- TNRC18 | chr7:5428089 G>C | 5'Flank (SNP) | VAF 24/289 reads (8%) | catalogued as rs971377724; called by muse, mutect2
- UBXN7 | c.73+70C>T | Intron (SNP) | VAF 22/280 reads (8%) | catalogued as rs757610036; called by muse, mutect2
- UQCRB | c.*813T>A | 3'UTR (SNP) | VAF 7/51 reads (14%) | called by muse, mutect2, varscan2
- UQCRB | c.*536A>G | 3'UTR (SNP) | VAF 27/188 reads (14%) | called by muse, mutect2, varscan2
- Y_RNA | chr7:75516221 C>T | 5'Flank (SNP) | VAF 27/226 reads (12%) | catalogued as rs1554485805; called by muse, mutect2, varscan2
- ZBTB16 | c.1269-34518G>A | Intron (SNP) | VAF 8/164 reads (5%) | catalogued as rs1399210170; called by muse, mutect2
